Somatic mutation profile of tumor specimen 0DI6L3 from CCDI case PBBVJX, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 8.7 years (3,191 days).
Specimen 0DI6L3: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dbb0309a-8641-4a80-872c-ab35b459353c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DI6KK (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c777bcea-86b9-474b-9b5b-51bbf38e5bea

The open-access MAF lists 16 somatic variants for this specimen: 8 protein-altering or splice-affecting, 6 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 6, 3'UTR 1, 5'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACSM6 | c.1381G>A p.G461S | Missense Mutation (SNP) | VAF 449/1057 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs530789365; called by muse, mutect2, varscan2
- MECOM | c.1852G>A p.E618K (on ENST00000468789 / NM_001105078.4; = p.E806K on NM_004991.4) | Missense Mutation (SNP) | VAF 534/1218 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.024); catalogued as rs771184600, COSV52959566; called by muse, mutect2, varscan2
- NUP210L | c.1022G>A p.R341Q | Missense Mutation (SNP) | VAF 66/1498 reads (4%) | SIFT tolerated (1); PolyPhen possibly damaging (0.47); catalogued as rs564027158; called by muse, mutect2
- AHNAK | c.562G>T p.E188* | Nonsense Mutation (SNP) | VAF 36/928 reads (4%) | called by muse, mutect2
- COL4A3 | c.2206G>T p.G736C | Missense Mutation (SNP) | VAF 52/1538 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PPIF | c.211G>C p.V71L | Missense Mutation (SNP) | VAF 347/900 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- TSPAN17 | c.254C>T p.A85V | Missense Mutation (SNP) | VAF 70/938 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZMYM3 | c.3605T>A p.V1202D | Missense Mutation (SNP) | VAF 361/376 reads (96%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.636); called by muse, mutect2, varscan2
- DCAF1 | c.2151C>T p.S717= | Silent (SNP) | VAF 32/556 reads (6%) | catalogued as rs575109915; called by muse, mutect2
- LAMA1 | c.1578C>T p.S526= | Silent (SNP) | VAF 335/862 reads (39%) | catalogued as rs368647137; called by muse, mutect2, varscan2
- NPHP3 | c.1635A>G p.Q545= | Silent (SNP) | VAF 39/1438 reads (3%) | catalogued as rs1204359841; called by muse, mutect2
- RAVER2 | c.279C>T p.D93= | Silent (SNP) | VAF 44/1479 reads (3%) | called by muse, mutect2
- SLC2A14 | c.1002C>T p.S334= | Silent (SNP) | VAF 106/767 reads (14%) | catalogued as rs746686521, COSV61588899; called by muse, mutect2, varscan2
- TMEM212 | c.423C>T p.Y141= | Silent (SNP) | VAF 62/1486 reads (4%) | catalogued as rs374938617; called by muse, mutect2
- GNRHR | c.*20G>C | 3'UTR (SNP) | VAF 22/593 reads (4%) | called by muse, mutect2
- MYRF | c.-71C>A | 5'UTR (SNP) | VAF 7/89 reads (8%) | called by muse, mutect2
